Somatic mutation profile of tumor specimen MP2PRT-PATGZN-TMP1-A (aliquot MP2PRT-PATGZN-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATGZN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (880 days).
Specimen MP2PRT-PATGZN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66573c29-3b6b-42ba-9037-560ed589430a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATGZN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATGZN-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e5e70a1-201d-40d0-a42b-c8a968a5a3fb

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 9, Silent 6, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 72/319 reads (23%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 28/452 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CCDC59 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 10/247 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV50257751; called by muse, mutect2
- FAM199X | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 92/1502 reads (6%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.018); catalogued as rs938706251, COSV55433610; called by muse, mutect2
- LTF | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 62/573 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs768123336, COSV51605296; called by muse, mutect2
- SLC6A8 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 62/518 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1211713, COSV53472014, COSV53472263; called by muse, mutect2, varscan2
- TTN | c.16328C>T p.T5443M (on ENST00000591111; = p.T4516M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/369 reads (11%) | PolyPhen benign (0.051); catalogued as rs770310501, COSV60188864; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID5B | c.961_962insGCCTT p.E321Gfs*14 | Frame Shift Ins (INS) | VAF 64/439 reads (15%) | called by mutect2, pindel, varscan2
- CLASP1 | c.2994C>G p.I998M | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- FAM193A | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 217/384 reads (57%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2, varscan2
- IFFO2 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 59/393 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGA | c.970_971insAAGGGAACCGGAC p.T324Kfs*8 | Frame Shift Ins (INS) | VAF 33/190 reads (17%) | called by mutect2, pindel
- APOC3 | c.42C>T p.L14= | Silent (SNP) | VAF 23/624 reads (4%) | catalogued as COSV99922682; called by muse, mutect2
- ASAP1 | c.750C>T p.F250= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as rs1451047046, COSV100727089; called by muse, mutect2, varscan2
- FLT1 | c.3585G>A p.K1195= | Silent (SNP) | VAF 57/224 reads (25%) | catalogued as COSV56746309; called by muse, mutect2, varscan2
- PCDH19 | c.462C>T p.Y154= | Silent (SNP) | VAF 36/1550 reads (2%) | catalogued as CM111237; called by muse, mutect2
- TLL2 | c.2514C>T p.D838= | Silent (SNP) | VAF 42/434 reads (10%) | catalogued as rs371883318; called by muse, mutect2
- TTYH3 | c.765C>T p.G255= | Silent (SNP) | VAF 263/566 reads (46%) | catalogued as rs779900502; called by muse, mutect2, varscan2
